TCGA case TCGA-CA-5256 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: ILSBio. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/17633a60-e12b-4a7c-bd8a-c16341ddc606

Demographics
Sex at birth: female; Race: asian; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Hepatic flexure of colon; Classification of tumor: primary; Age at diagnosis: 54.2 years (19,785 days); Year of diagnosis: 2010; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 379 days (1.0 years).
   Pathology details: Consistent pathology review: Yes; Non nodal tumor deposits: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Days to treatment start: 20 days; Days to treatment end: 206 days; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; Disease response: Tumor Free.
- Days to follow up: 65 days; Disease response: Tumor Free.
- Days to follow up: 379 days (1.0 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 52 kg; Height: 160 cm; BMI: 20.3.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CA-5256-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 1; Shortest dimension: 0.5.
  Slide TCGA-CA-5256-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 10; Percent stromal cells: 10.
  Slide TCGA-CA-5256-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 15.
- Sample TCGA-CA-5256-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CA-5256-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Hepatic Flexure; Lymph nodes examined: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Mismatch rep proteins tested by IHC: No.
- Drug treatment 2: Pharmaceutical therapy drug name: 5-Fluorouracil.
- Drug treatment 3: Pharmaceutical therapy drug name: Folinic Acid.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 379 days; disease-specific survival: no event (censored), 379 days; disease-free interval: no event (censored), 379 days; progression-free interval: no event (censored), 379 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CA-5256-01A-01D-1406-01): tumor purity 0.66, ploidy 3.73, whole-genome doublings 1.
